Somatic mutation profile of tumor specimen TCGA-LP-A4AX-01A (aliquot TCGA-LP-A4AX-01A-12D-A243-09) from TCGA case TCGA-LP-A4AX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 45.3 years (16,544 days).
Specimen TCGA-LP-A4AX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b958d21-a939-4c39-95d4-d18a5e07c09b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A4AX-10A (Blood Derived Normal), aliquot TCGA-LP-A4AX-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f91cf41d-59e1-476e-a6fc-60156b748434

The open-access MAF lists 51 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 14, Nonsense Mutation 4, In Frame Del 3, Splice Site 2, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56687076; called by muse, mutect2, varscan2
- ATG2B | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1177016344, COSV63423324; called by muse, mutect2, varscan2
- BACH1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV54519160; called by muse, mutect2, varscan2
- C1orf21 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52406130; called by muse, mutect2, varscan2
- DOT1L | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV67110010; called by muse, mutect2, varscan2
- DZIP1L | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59521172; called by muse, mutect2, varscan2
- EGFL8 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.081); catalogued as COSV61247741, COSV61248846; called by muse, mutect2, varscan2
- FLG2 | c.6051G>C p.Q2017H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101166317, COSV66169051; called by muse, mutect2, varscan2
- FRY | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV66570787; called by muse, mutect2, varscan2
- H4C3 | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV58090630; called by muse, mutect2, varscan2
- HTR4 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV58795845; called by muse, mutect2, varscan2
- NET1 | c.272G>C p.R91T (on ENST00000355029 / NM_001047160.3; = p.R37T on NM_005863.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61791568; called by muse, mutect2
- NEXMIF | c.2350A>C p.S784R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50033708; called by muse, mutect2, varscan2
- NLN | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs1198493032, COSV66765981; called by muse, mutect2, varscan2
- PDS5A | c.2567C>G p.S856C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57826180; called by muse, mutect2, varscan2
- PKHD1L1 | c.7472G>A p.R2491K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65736033, COSV65743771; called by muse, mutect2, varscan2
- PTCHD1 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV65060233; called by muse, mutect2, varscan2
- PTK2B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs267601879, COSV57757405; called by muse, mutect2, varscan2
- PTPRC | c.3433A>T p.K1145* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV61412366; called by muse, mutect2
- RAD21 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs754768368, COSV52059424; called by mutect2, varscan2
- RUNX1T1 | c.1480A>T p.K494* (on ENST00000265814 / NM_001198628.1; = p.K467* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV56148199; called by muse, mutect2, varscan2
- SLC4A1AP | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV58135124; called by muse, mutect2, varscan2
- ST3GAL2 | c.798C>G p.H266Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | PolyPhen possibly damaging (0.879); catalogued as COSV61596824; called by muse, mutect2, varscan2
- SYNE1 | c.20621C>G p.T6874R (on ENST00000367255 / NM_182961.4; = p.T6803R on NM_033071.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54993469; called by muse, mutect2, varscan2
- TAB2 | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV53852770; called by muse, mutect2
- TOP2A | c.1794G>T p.W598C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70732647; called by muse, mutect2, varscan2
- UBE2T | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV66153364, COSV66153477; called by muse, mutect2, varscan2
- VPS8 | c.3181C>T p.Q1061* (on ENST00000625842 / NM_001349294.1; = p.Q1059* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99804130; called by muse, mutect2
- XRRA1 | c.2298G>C p.E766D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); catalogued as COSV55132679; called by muse, mutect2, varscan2
- EML3 | c.1501_1504+9del p.X501_splice | Splice Site (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- HOXA3 | c.138_158del p.H46_L52del | In Frame Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel
- KIF7 | c.3969_3980del p.P1324_E1327del | In Frame Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- KRT10 | c.1747_1748+2dup | Splice Region (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- MYH7 | c.5261_5283+21del p.X1754_splice | Splice Site (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel
- RGL2 | c.252_254del p.P86del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ACSS2 | c.1692C>T p.I564= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV53624984; called by muse, mutect2, varscan2
- ARNT2 | c.378C>T p.G126= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs752823394, COSV57585654, COSV57586428; called by muse, mutect2, varscan2
- CDH4 | c.1440G>C p.L480= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV64656047; called by muse, mutect2, varscan2
- CHD7 | c.8589T>C p.A2863= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV71111032; called by muse, mutect2, varscan2
- CSE1L | c.1212C>A p.I404= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV53702128; called by muse, mutect2, varscan2
- HTR4 | c.891C>T p.F297= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1206810413, COSV58795871; called by muse, mutect2, varscan2
- ITIH1 | c.780C>T p.Y260= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs372878494; called by muse, mutect2, varscan2
- MYH10 | c.5553G>A p.L1851= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs867268752, COSV52602109; called by muse, mutect2, varscan2
- MYT1L | c.1542C>T p.H514= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs750963882, COSV67721195; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB6 | c.1602C>T p.R534= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs1371567466, COSV50699537; called by muse, mutect2, varscan2
- SMIM14 | c.15A>G p.G5= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV55904135; called by muse, mutect2, varscan2
- SRSF3 | c.189C>T p.V63= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV59671179; called by muse, mutect2, varscan2
- TEFM | c.615A>C p.G205= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs760498412, COSV58974978; called by muse, mutect2, varscan2
- TFCP2L1 | c.1218G>C p.L406= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV55291446; called by muse, mutect2, varscan2
- SSPOP | n.9778G>A | RNA (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65130545; called by muse, mutect2, varscan2
- TTN | c.10361-5192C>G | Intron (SNP) | VAF 21/119 reads (18%) | catalogued as COSV60088606; called by muse, mutect2, varscan2
